Somatic mutation profile of tumor specimen TARGET-30-PASYPX-01A (aliquot TARGET-30-PASYPX-01A-01D) from TARGET case TARGET-30-PASYPX, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.1 years (1,514 days).
Specimen TARGET-30-PASYPX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5d15056-2f76-499e-ac93-178764f6866b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASYPX-10A (Blood Derived Normal), aliquot TARGET-30-PASYPX-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41b6f7da-dbd1-44a8-8f66-c97e8a7ec56c

The open-access MAF lists 43 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Nonsense Mutation 3, 5'UTR 2, Intron 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL6B | c.1231C>A p.Q411K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV50516669; called by muse, mutect2, varscan2
- AHR | c.1600A>T p.S534C | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.765); catalogued as COSV54124987; called by muse, mutect2, varscan2
- AKAP4 | c.1579G>T p.D527Y | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62074972; called by muse, mutect2, varscan2
- ATP13A5 | c.2559C>A p.N853K | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60872351, COSV60877210; called by muse, mutect2, varscan2
- DBNDD2 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs370599286; called by muse, mutect2, varscan2
- DEFB113 | c.147G>A p.W49* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs759456897, COSV59038285; called by muse, mutect2, varscan2
- EIF2AK4 | c.4771G>A p.E1591K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs376905395; called by muse, mutect2, varscan2
- EPG5 | c.3517T>C p.C1173R | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56353187; called by muse, mutect2, varscan2
- EPRS1 | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV65100449; called by muse, mutect2, varscan2
- HCN4 | c.2617C>G p.P873A | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as COSV56085592; called by mutect2, varscan2
- JAKMIP1 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.32); catalogued as rs765708383, COSV51532503; called by muse, mutect2, varscan2
- LEF1 | c.952G>T p.V318F | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54470262, COSV54471390; called by muse, mutect2, varscan2
- MROH8 | c.492A>G p.I164M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs750153428, COSV54122536; called by muse, mutect2, varscan2
- OR51S1 | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV59059264; called by muse, mutect2, varscan2
- OR6C70 | c.530G>T p.C177F | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV59245124; called by muse, mutect2, varscan2
- PRKAG3 | c.936C>G p.D312E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.578); catalogued as COSV52102983; called by muse, mutect2, varscan2
- PTPRH | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 13/30 reads (43%) | catalogued as COSV54747896; called by mutect2, varscan2
- SBF1 | c.3511G>T p.V1171L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62369281; called by muse, mutect2, varscan2
- SCN5A | c.5573C>A p.T1858N (on ENST00000333535 / NM_198056.3; = p.T1857N on NM_000335.5) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61132960; called by muse, mutect2, varscan2
- SEZ6L2 | c.2397C>A p.C799* (on ENST00000308713 / NM_001114099.3; = p.C729* on NM_012410.4) | Nonsense Mutation (SNP) | VAF 18/51 reads (35%) | catalogued as COSV58101558; called by muse, varscan2
- SSH1 | c.2973C>A p.D991E | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58458368; called by muse, mutect2, varscan2
- SYP | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54296271; called by mutect2, varscan2
- TEP1 | c.4177C>T p.P1393S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.684); catalogued as rs753467724, COSV52996387; called by muse, mutect2, varscan2
- TEX2 | c.2249G>T p.G750V (on ENST00000583097 / NM_001288733.2; = p.G757V on NM_018469.5) | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51983710; called by muse, mutect2, varscan2
- TMCO6 | c.233C>G p.T78R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.48); catalogued as rs1299332945, COSV52800574; called by muse, mutect2, varscan2
- TNXB | c.11534A>T p.Q3845L (on ENST00000647633; = p.Q3598L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV64483859; called by muse, mutect2, varscan2
- ZMYM1 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs777278071, COSV63252700; called by mutect2, varscan2
- TCF12 | c.1036-2A>T p.X346_splice | Splice Site (SNP) | VAF 20/68 reads (29%) | called by muse, varscan2
- C7 | c.1758T>C p.G586= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs758223072, COSV57477500; called by muse, mutect2, varscan2
- DUOX1 | c.3880C>A p.R1294= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs372852972, COSV58484119; called by muse, mutect2, varscan2
- FAM131A | c.801A>C p.P267= (on ENST00000310585; = p.P298= on NM_144635.5) | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV55602950; called by muse, mutect2, varscan2
- FBXO15 | c.702A>T p.P234= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV54047095; called by muse, mutect2, varscan2
- FCGBP | c.8163G>A p.E2721= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as rs1351304935, COSV55445786; called by muse, mutect2, varscan2
- LAMC3 | c.1959G>A p.E653= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV63093723; called by muse, mutect2, varscan2
- PCDHGA11 | c.804G>A p.T268= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as rs377701820; called by muse, mutect2, varscan2
- STAT1 | c.1452G>A p.L484= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV63116975; called by muse, mutect2, varscan2
- SYNE2 | c.4245C>A p.G1415= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV59960215; called by muse, mutect2, varscan2
- TTC5 | c.1299G>T p.V433= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV51871690; called by muse, varscan2
- ADAR | c.-940G>A | 5'UTR (SNP) | VAF 23/56 reads (41%) | catalogued as rs759778076, COSV52717509, COSV99426812; called by muse, mutect2, varscan2
- IL9R | c.29-1430G>T | Intron (SNP) | VAF 64/174 reads (37%) | called by muse, mutect2, varscan2
- MFSD4B | c.*556C>A | 3'UTR (SNP) | VAF 45/172 reads (26%) | catalogued as COSV64349249; called by muse, mutect2, varscan2
- SUPT20HL2 | c.-735G>A | 5'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- TTN | c.10360+2518G>A | Intron (SNP) | VAF 18/40 reads (45%) | catalogued as COSV60207181; called by muse, mutect2, varscan2
